Somatic mutation profile of tumor specimen C3L-03143-01 (aliquot CPT0234080006) from CPTAC case C3L-03143, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IVB; FIGO stage: Stage IVB; Age at diagnosis: 67.2 years (24,543 days).
Specimen C3L-03143-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d391a0b-acae-4fbf-8b61-4cb20f82cfb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03143-71 (Blood Derived Normal), aliquot CPT0234140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f38d0041-875b-48db-a0cf-3b0ac8d0ab3d

The open-access MAF lists 102 somatic variants for this specimen: 71 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 22, RNA 3, Intron 3, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 2, Nonstop Mutation 1, Splice Region 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 84/199 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 290/376 reads (77%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CA12 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 126/166 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1045086909; called by muse, mutect2, varscan2
- CCDC116 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1472273282; called by muse, mutect2, varscan2
- CD6 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs912829735; called by muse, mutect2
- CEMIP2 | c.3779C>T p.T1260M | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs114226382; called by muse, mutect2, varscan2
- CERS1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs555889038, COSV55928803; called by muse, mutect2, varscan2
- CSMD2 | c.10390C>T p.R3464C | Missense Mutation (SNP) | VAF 95/1006 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs376862875; called by muse, mutect2
- CSNK1G3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1182001385; called by muse, mutect2
- DSG2 | c.2604T>A p.H868Q | Missense Mutation (SNP) | VAF 160/457 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV55199013; called by muse, mutect2, varscan2
- EPPK1 | c.4539G>T p.E1513D | Missense Mutation (SNP) | VAF 22/705 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV73261060; called by muse, mutect2
- F13B | c.1182G>C p.E394D | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100803295, COSV66374840; called by muse, mutect2, varscan2
- HSPA12B | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.197); catalogued as rs375250880; called by muse, mutect2, varscan2
- IL37 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs370690543; called by muse, mutect2, varscan2
- LARP1 | c.3248A>G p.K1083R (on ENST00000518297 / NM_033551.3; = p.K1006R on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.971); catalogued as rs761756581; called by muse, mutect2, varscan2
- LTBP4 | c.4801C>T p.R1601C (on ENST00000308370 / NM_001042544.1; = p.R1564C on NM_003573.2) | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1003760816; called by muse, mutect2
- MARCHF2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as rs763102811, COSV99294889; called by muse, mutect2, varscan2
- MIB2 | c.1066G>C p.G356R | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100599006; called by muse, mutect2, varscan2
- NRXN3 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as COSV55365073; called by muse, mutect2, varscan2
- PAPPA2 | c.2672G>A p.R891H | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs769584951, COSV100867259, COSV62772532; called by muse, mutect2, varscan2
- PKN1 | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 11/368 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1288299805; called by muse, mutect2
- POLD4 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1388330911; called by muse, mutect2, varscan2
- PRKD2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1026645138; called by muse, mutect2, varscan2
- SLC4A11 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 134/513 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs185463872; called by muse, mutect2, varscan2
- SLFN13 | c.2564G>C p.R855P | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53194499; called by muse, mutect2
- SPEN | c.4609G>A p.E1537K | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104424587; called by muse, mutect2
- SPOCK3 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs377199025; called by muse, mutect2, varscan2
- SUN1 | c.281G>A p.R94H (on ENST00000405266 / NM_001367651.1; = p.R44H on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs112598200; ClinVar: uncertain significance; called by muse, mutect2
- TMC6 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 162/469 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1331828535; called by muse, mutect2, varscan2
- YME1L1 | c.1765G>C p.D589H (on ENST00000326799 / NM_139312.3; = p.D532H on NM_014263.4) | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1433557613; called by muse, mutect2, varscan2
- ZNF264 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 98/302 reads (32%) | catalogued as rs554438584; called by muse, mutect2, varscan2
- ADGRL3 | c.4463C>T p.S1488F (on ENST00000506720 / NM_001322402.2; = p.S1377F on NM_015236.6) | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CALM2 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.5059G>C p.E1687Q | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CRY2 | c.1182G>C p.E394D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CRYBG3 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- DMXL1 | c.5910T>G p.S1970R | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- DNALI1 | c.273G>C p.L91F (on ENST00000296218; = p.L69F on NM_003462.5) | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML4 | c.1436T>C p.M479T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EZR | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GLT8D1 | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITGB6 | c.206del p.G69Dfs*4 | Frame Shift Del (DEL) | VAF 62/198 reads (31%) | called by mutect2, pindel, varscan2
- JAKMIP1 | c.2076G>A p.M692I | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KCMF1 | c.1068G>T p.M356I | Missense Mutation (SNP) | VAF 125/184 reads (68%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- KDM4C | c.1400A>C p.E467A | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- KMT2E | c.5431_5440del p.F1811Ifs*58 | Frame Shift Del (DEL) | VAF 37/397 reads (9%) | called by mutect2, pindel
- LRRK1 | c.4289A>C p.Y1430S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LZTS2 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 50/256 reads (20%) | called by muse, mutect2, varscan2
- MAGI3 | c.4434_*17del | Nonstop Mutation (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel
- MLXIP | c.2535T>A p.F845L | Missense Mutation (SNP) | VAF 92/154 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PHKG2 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 180/564 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PITPNC1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PTK2 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.395); called by muse, mutect2
- PTPN23 | c.4595C>G p.A1532G | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.052); called by muse, varscan2
- RAPGEF5 | c.1237C>T p.R413* (on ENST00000401957 / NM_001367602.2; = p.R716* on NM_012294.5) | Nonsense Mutation (SNP) | VAF 50/168 reads (30%) | called by muse, mutect2, varscan2
- RARS2 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ROBO1 | c.4913G>C p.R1638T | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC27A5 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPATA31A1 | c.1696C>G p.Q566E | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.301); called by mutect2, varscan2
- TNPO1 | c.2693T>C p.V898A | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TOP2A | c.2951G>A p.G984E | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TOP2A | c.2515G>C p.E839Q | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TPTE | c.1566A>C p.K522N (on ENST00000618007 / NM_199261.4; = p.K504N on NM_199259.4) | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2
- TRAF3IP3 | c.1465T>G p.S489A | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRPV4 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 165/404 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- VRK2 | c.526T>G p.Y176D | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- XPNPEP1 | c.828C>T p.I276= | Splice Region (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- ZNF417 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 129/814 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF518A | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF638 | c.3586G>C p.E1196Q | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2
- ZSCAN29 | c.1479G>C p.L493F | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC011462.1 | c.342C>T p.R114= | Silent (SNP) | VAF 73/266 reads (27%) | catalogued as rs143167070; called by muse, mutect2, varscan2
- ACVR2B | c.1171T>C p.L391= | Silent (SNP) | VAF 360/682 reads (53%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.549C>T p.D183= | Silent (SNP) | VAF 59/242 reads (24%) | catalogued as rs754956697, COSV57044287; called by muse, mutect2, varscan2
- ANKRD24 | c.2601G>A p.Q867= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2
- ASB4 | c.729C>T p.A243= | Silent (SNP) | VAF 54/296 reads (18%) | catalogued as rs1387140013, COSV57943009; called by muse, mutect2, varscan2
- ATG9B | c.2217A>G p.A739= | Silent (SNP) | VAF 123/276 reads (45%) | called by muse, mutect2, varscan2
- COL6A3 | c.4677C>T p.F1559= | Silent (SNP) | VAF 71/322 reads (22%) | catalogued as rs147215386; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FAT1 | c.8865A>G p.T2955= | Silent (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- HCN1 | c.1551C>T p.H517= | Silent (SNP) | VAF 86/453 reads (19%) | catalogued as rs1007416378, COSV100302170, COSV57494940; ClinVar: likely benign; called by muse, mutect2, varscan2
- JUP | c.1692C>T p.T564= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs781958880, COSV100159923; called by muse, mutect2, varscan2
- KCTD3 | c.300C>T p.Y100= | Silent (SNP) | VAF 80/166 reads (48%) | catalogued as rs374541317; called by muse, mutect2, varscan2
- KLHL34 | c.315C>T p.A105= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as rs1482662897, COSV101070011; called by muse, mutect2
- MAP2 | c.4638C>T p.S1546= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as rs1288669496; called by muse, mutect2, varscan2
- OCRL | c.1158G>A p.R386= | Silent (SNP) | VAF 12/159 reads (8%) | catalogued as rs1404912774; called by muse, mutect2
- PAPLN | c.1545G>A p.P515= (on ENST00000554301; = p.P488= on NM_173462.4) | Silent (SNP) | VAF 73/441 reads (17%) | catalogued as rs369082075, COSV53724155; called by muse, mutect2, varscan2
- PLEC | c.1929G>T p.V643= (on ENST00000322810 / NM_201380.4; = p.V533= on NM_000445.5) | Silent (SNP) | VAF 129/812 reads (16%) | called by muse, mutect2
- POMC | c.312C>T p.R104= | Silent (SNP) | VAF 58/217 reads (27%) | catalogued as rs1020449183; called by muse, mutect2, varscan2
- PRRT4 | c.39C>T p.C13= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- RGL3 | c.282C>T p.P94= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs749788033; called by muse, mutect2, varscan2
- SEMA4A | c.1863C>T p.L621= | Silent (SNP) | VAF 112/846 reads (13%) | catalogued as rs574793313; called by muse, mutect2, varscan2
- SLCO3A1 | c.2019G>A p.L673= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- TESPA1 | c.54C>G p.L18= | Silent (SNP) | VAF 35/103 reads (34%) | called by muse, mutect2, varscan2
- AC079612.1 | n.635G>A | RNA (SNP) | VAF 32/134 reads (24%) | catalogued as rs1411004837; called by muse, mutect2, varscan2
- FAM153A | c.-56-2289C>T | Intron (SNP) | VAF 64/240 reads (27%) | catalogued as rs763412450; called by muse, mutect2, varscan2
- MAPK8IP1P2 | n.121C>A | RNA (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- MGAM | c.4618+12850G>T | Intron (SNP) | VAF 24/28 reads (86%) | called by muse, mutect2
- MIR7-2 | n.65C>T | RNA (SNP) | VAF 63/303 reads (21%) | catalogued as rs756560165; called by muse, mutect2, varscan2
- NDUFAF3 | c.*32dup | 3'UTR (INS) | VAF 130/482 reads (27%) | called by mutect2, varscan2
- PHF21A | c.1785+33C>T | Intron (SNP) | VAF 15/40 reads (38%) | catalogued as rs1420199618, COSV57658220; called by muse, mutect2, varscan2
- PPDPFL | c.*722A>G | 3'UTR (SNP) | VAF 284/472 reads (60%) | called by muse, mutect2, varscan2
- RPLP1 | chr15:69458738 C>A | 3'Flank (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
